Somatic mutation profile of tumor specimen MBCProject_4574_T2_WES (aliquot MBCProject_4574_T2_WES_1) from CMI case MBCProject_4574, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 59.4 years (21,686 days).
Specimen MBCProject_4574_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8108018e-29cb-4e9d-9302-7dc8579bc18e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4574_SALIVA (Saliva), aliquot MBCProject_4574_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/780fe289-c386-4c62-8707-f920f1bb9811

The open-access MAF lists 78 somatic variants for this specimen: 46 protein-altering or splice-affecting, 22 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 22, Intron 5, Nonsense Mutation 4, 5'UTR 3, 3'Flank 2, Frame Shift Ins 2, Splice Region 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 23/114 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.2260G>A p.A754T | Missense Mutation (SNP) | VAF 80/358 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.258); catalogued as COSV53932627; called by muse, varscan2
- ATG101 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs367943792; called by muse, mutect2, varscan2
- DOCK1 | c.1817C>T p.T606M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752613726; called by muse, varscan2
- EEF1G | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as rs748691710; called by muse, mutect2, varscan2
- GGCX | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 24/399 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs1309849861, COSV99290138; called by muse, mutect2
- GLI3 | c.4382C>T p.S1461F | Missense Mutation (SNP) | VAF 438/870 reads (50%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs149543947, COSV67885798; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HIF1A | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs757398838; called by muse, mutect2, varscan2
- IFI27 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs752772349; called by muse, mutect2, varscan2
- KCNU1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 25/425 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs180964986, COSV67755904; called by muse, mutect2
- KIAA1109 | c.7874C>T p.S2625F | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV99177248; called by muse, mutect2, varscan2
- KLHL38 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 57/508 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV58086042; called by muse, mutect2, varscan2
- LTV1 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs148483467, COSV52786305; called by muse, mutect2, varscan2
- MAPK1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 76/305 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53187829; called by muse, mutect2, varscan2
- MRPL28 | c.219dup p.E74Rfs*38 | Frame Shift Ins (INS) | VAF 53/247 reads (21%) | catalogued as rs762068708; called by mutect2, pindel, varscan2
- MYT1 | c.2831C>T p.P944L | Missense Mutation (SNP) | VAF 60/370 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs748668395; called by muse, mutect2, varscan2
- NF1 | c.2846G>A p.G949E | Missense Mutation (SNP) | VAF 50/424 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as CD1512853; called by muse, mutect2, varscan2
- PRKDC | c.10426C>G p.P3476A | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV58065281; called by muse, mutect2, varscan2
- SLC6A6 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1400003153, COSV62649266; called by muse, mutect2, varscan2
- VWA5B2 | c.3023G>A p.R1008H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs961560948; called by muse, mutect2, varscan2
- WNT2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 75/642 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs757215951, COSV55411110; called by muse, mutect2, varscan2
- AFDN | c.2844del p.P949Qfs*8 | Frame Shift Del (DEL) | VAF 25/127 reads (20%) | called by mutect2, pindel, varscan2
- C4orf3 | c.*1C>G | Splice Region (SNP) | VAF 57/224 reads (25%) | called by muse, mutect2, varscan2
- CAMK2A | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCN2 | c.516_517dup p.T173Kfs*23 | Frame Shift Ins (INS) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- DCAF6 | c.1748A>T p.E583V (on ENST00000312263 / NM_001349778.1; = p.E603V on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 203/325 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- FAM117B | c.1628C>T p.T543I | Missense Mutation (SNP) | VAF 17/519 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); called by muse, mutect2
- GCC2 | c.4024G>A p.A1342T | Missense Mutation (SNP) | VAF 14/407 reads (3%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2
- GRM6 | c.2275C>T p.L759F | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIAA0586 | c.1907T>C p.V636A (on ENST00000619416 / NM_001244190.2; = p.V575A on NM_014749.5) | Missense Mutation (SNP) | VAF 136/472 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ONECUT2 | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2B11 | c.315T>G p.Y105* | Nonsense Mutation (SNP) | VAF 11/197 reads (6%) | called by muse, mutect2
- PCNX3 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | called by muse, varscan2
- PLCL1 | c.1148C>A p.S383* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- SHC4 | c.1112A>G p.D371G | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC5A7 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- SLC9B2 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 49/382 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TASOR2 | c.1857C>G p.S619R | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TRIB3 | c.710A>T p.Y237F | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USH2A | c.5589G>A p.M1863I | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.018); called by muse, mutect2
- USH2A | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 38/605 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.131); called by muse, mutect2
- XBP1 | c.321_323del p.E108del | In Frame Del (DEL) | VAF 72/279 reads (26%) | called by pindel, varscan2
- ZFHX2 | c.3067G>T p.A1023S | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT tolerated (0.45); called by muse, mutect2, varscan2
- ZNF337 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 14/289 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2
- ZNF585A | c.803G>A p.R268K (on ENST00000292841 / NM_001288800.2; = p.R213K on NM_152655.3) | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2
- ZSCAN4 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- CCDC66 | c.2265C>T p.G755= (on ENST00000394672 / NM_001353147.1; = p.G721= on NM_001012506.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 44/193 reads (23%) | called by muse, mutect2, varscan2
- CD27 | c.609C>T p.F203= | Silent (SNP) | VAF 130/485 reads (27%) | catalogued as rs772814106, COSV56946597; called by muse, mutect2, varscan2
- CDR2 | c.531C>T p.F177= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs747406634; called by muse, varscan2
- CNTLN | c.3459G>A p.L1153= | Silent (SNP) | VAF 24/240 reads (10%) | called by muse, mutect2
- EXOC7 | c.1104C>T p.V368= (on ENST00000335146 / NM_001145297.4; = p.V286= on NM_015219.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/297 reads (11%) | called by muse, mutect2, varscan2
- GALNT7 | c.273C>T p.A91= | Silent (SNP) | VAF 93/585 reads (16%) | called by muse, mutect2, varscan2
- KRTAP17-1 | c.129C>T p.C43= | Silent (SNP) | VAF 10/236 reads (4%) | catalogued as rs368577794, COSV61971934, COSV61972349; called by muse, mutect2
- MROH9 | c.2196C>T p.N732= | Silent (SNP) | VAF 18/266 reads (7%) | called by muse, mutect2
- MXRA5 | c.8250C>T p.T2750= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs760983208, COSV54240280; called by muse, mutect2, varscan2
- OR14A2 | c.180C>T p.F60= | Silent (SNP) | VAF 20/293 reads (7%) | called by muse, mutect2
- PDZRN4 | c.732T>C p.N244= | Silent (SNP) | VAF 23/195 reads (12%) | called by muse, mutect2, varscan2
- POLN | c.633G>A p.L211= | Silent (SNP) | VAF 32/185 reads (17%) | catalogued as rs1290201527; called by muse, mutect2, varscan2
- PSKH2 | c.630C>T p.S210= | Silent (SNP) | VAF 27/243 reads (11%) | catalogued as rs376242267; called by muse, mutect2, varscan2
- SCNN1A | c.310C>T p.L104= | Silent (SNP) | VAF 143/756 reads (19%) | called by muse, mutect2, varscan2
- SCRT2 | c.225G>A p.P75= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs767324211; called by muse, varscan2
- SIX3 | c.438C>T p.R146= | Silent (SNP) | VAF 43/237 reads (18%) | called by muse, mutect2, varscan2
- STXBP4 | c.273C>T p.T91= | Silent (SNP) | VAF 35/287 reads (12%) | called by muse, mutect2, varscan2
- TNS2 | c.2631G>A p.P877= (on ENST00000314250 / NM_170754.4; = p.P887= on NM_015319.2) | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as rs113627018, COSV100036714; called by muse, mutect2
- USP21 | c.669G>A p.L223= | Silent (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- XRCC3 | c.813G>A p.G271= | Silent (SNP) | VAF 56/265 reads (21%) | called by muse, mutect2, varscan2
- ZNF521 | c.693T>C p.S231= | Silent (SNP) | VAF 20/259 reads (8%) | called by muse, mutect2
- ZNF573 | c.1491C>A p.P497= (on ENST00000536220 / NM_001172692.1; = p.P439= on NM_152360.3) | Silent (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- DENND10 | c.-28C>T | 5'UTR (SNP) | VAF 7/35 reads (20%) | catalogued as rs1045493691; called by muse, mutect2, varscan2
- FAM149B1 | chr10:73247355 G>A | 3'Flank (SNP) | VAF 56/139 reads (40%) | called by muse, mutect2, varscan2
- FOXA1 | c.-1G>A | 5'UTR (SNP) | VAF 239/647 reads (37%) | called by muse, mutect2, varscan2
- FXYD2 | c.65-10C>A | Intron (SNP) | VAF 28/178 reads (16%) | catalogued as COSV52642127; called by muse, mutect2, varscan2
- HMGA1 | c.-4G>A | 5'UTR (SNP) | VAF 71/481 reads (15%) | called by muse, mutect2, varscan2
- MYSM1 | c.320+12T>C | Intron (SNP) | VAF 52/195 reads (27%) | catalogued as rs371527682; called by muse, mutect2, varscan2
- REV3L | c.9043-618T>A | Intron (SNP) | VAF 6/64 reads (9%) | catalogued as rs1356395055; called by muse, mutect2
- SH3D21 | chr1:36323103 C>T | 3'Flank (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- SPAG9 | c.590+725G>A | Intron (SNP) | VAF 70/241 reads (29%) | called by muse, mutect2, varscan2
- STIM1 | c.1541+196C>T | Intron (SNP) | VAF 82/460 reads (18%) | catalogued as rs534741528; called by muse, mutect2, varscan2
